Somatic mutation profile of tumor specimen C3L-08872-03 (aliquot CPT0485820009) from CPTAC case C3L-08872, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.6 years (27,265 days).
Specimen C3L-08872-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 623eff29-65a8-44d4-a09e-fcefee28688f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08872-31 (Blood Derived Normal), aliquot CPT0485890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4db7ee0c-f332-41a2-9963-f99ac2c90da7

The open-access MAF lists 2,227 somatic variants for this specimen: 1,624 protein-altering or splice-affecting, 536 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,202, Silent 536, Frame Shift Del 269, Frame Shift Ins 73, Nonsense Mutation 47, Intron 36, 3'UTR 16, Splice Region 12, In Frame Del 11, 5'Flank 7, Splice Site 6, 5'UTR 3.

Variants (750 of 2,227; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD164 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 44/221 reads (20%) | catalogued as rs876661402, CM158501; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXP3 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 93/477 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs122467170, CM010058; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSPG2 | c.7006+1G>A p.X2336_splice | Splice Site (SNP) | VAF 64/354 reads (18%) | catalogued as rs778653296, CS065567, COSV65970478; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 56/271 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 130/284 reads (46%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MYH7 | c.4135G>A p.A1379T | Missense Mutation (SNP) | VAF 60/352 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as rs397516202, CM020288; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 38/181 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RIN2 | c.1878del p.I627Sfs*4 (on ENST00000255006 / NM_001242581.1; = p.I578Sfs*4 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 56/310 reads (18%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 69/333 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 90/440 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.436); catalogued as rs1364398348, COSV57925016; called by muse, mutect2, varscan2
- AATK | c.1309G>A p.G437S (on ENST00000326724 / NM_001080395.3; = p.G334S on NM_004920.2) | Missense Mutation (SNP) | VAF 148/681 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as rs879641488; called by muse, mutect2, varscan2
- ABCA10 | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1388474248, COSV52220907, COSV52221637; called by muse, mutect2, varscan2
- ABCB5 | c.3157G>A p.G1053S (on ENST00000404938 / NM_001163941.2; = p.G608S on NM_178559.6) | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1421780453; called by muse, mutect2, varscan2
- ABHD16A | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 139/577 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.215); catalogued as rs1271413764, COSV65451551; called by muse, mutect2, varscan2
- ABI2 | c.596G>A p.R199H (on ENST00000295851 / NM_001375719.1; = p.R193H on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs1402325484, COSV99652368; called by muse, mutect2, varscan2
- ABTB2 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 97/428 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as rs554984925; called by muse, mutect2, varscan2
- AC126283.2 | c.111del p.K37Nfs*65 | Frame Shift Del (DEL) | VAF 38/295 reads (13%) | catalogued as rs1560546604; called by mutect2, pindel, varscan2
- ACACB | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 19/541 reads (4%) | catalogued as rs1274313088; called by muse, mutect2
- ACE2 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as rs140473595; called by muse, varscan2
- ACER2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV104417261; called by muse, mutect2, varscan2
- ACOX3 | c.1759G>A p.V587M | Missense Mutation (SNP) | VAF 108/541 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1239766706, COSV62713499; called by muse, mutect2, varscan2
- ACVR1B | c.85del p.V29Sfs*57 | Frame Shift Del (DEL) | VAF 54/317 reads (17%) | catalogued as rs1425551425; called by mutect2, pindel, varscan2
- ACVR1B | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 78/368 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as COSV57777110; called by muse, mutect2, varscan2
- ACVR1B | c.1018A>G p.N340D | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99231374; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 88/256 reads (34%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM22 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs558399747, COSV55971830; called by muse, mutect2, varscan2
- ADAMTS1 | c.1627G>A p.G543S | Missense Mutation (SNP) | VAF 64/314 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as rs186276457; called by muse, varscan2
- ADAMTS3 | c.1067del p.L356* | Frame Shift Del (DEL) | VAF 66/359 reads (18%) | catalogued as rs1424429467; called by mutect2, pindel, varscan2
- ADAMTS5 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 103/453 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); catalogued as COSV99537948; called by muse, mutect2, varscan2
- ADGRB1 | c.4178C>T p.P1393L | Missense Mutation (SNP) | VAF 59/352 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1482546030, COSV60094295; called by muse, mutect2, varscan2
- ADGRL1 | c.3259G>A p.A1087T (on ENST00000340736 / NM_001008701.3; = p.A1082T on NM_014921.5) | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.062); catalogued as rs576856623, COSV61563740; called by muse, varscan2
- ADGRV1 | c.12911C>T p.T4304M | Missense Mutation (SNP) | VAF 58/347 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs145209242, COSV67989514; called by muse, mutect2, varscan2
- ADSL | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV53407861, COSV99342574; called by muse, mutect2, varscan2
- AFDN | c.509del p.K170Rfs*53 | Frame Shift Del (DEL) | VAF 75/336 reads (22%) | catalogued as rs1431558072; called by mutect2, pindel, varscan2
- AFF1 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 112/461 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as rs770342922; called by muse, mutect2, varscan2
- AGL | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs1332737486; called by muse, mutect2, varscan2
- AGRN | c.1885G>A p.G629S | Missense Mutation (SNP) | VAF 116/516 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.203); catalogued as rs150061172; called by muse, varscan2
- AGTPBP1 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.316); catalogued as rs778431392; called by muse, mutect2, varscan2
- AHNAK | c.4612G>A p.D1538N | Missense Mutation (SNP) | VAF 78/384 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs1307806147, COSV57226102; called by muse, mutect2, varscan2
- AIFM2 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 81/360 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs753854619, COSV57160013; called by muse, mutect2, varscan2
- AIMP2 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 106/506 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs760946189, COSV52242131; called by muse, mutect2, varscan2
- AIPL1 | c.59del p.G20Afs*14 | Frame Shift Del (DEL) | VAF 40/313 reads (13%) | catalogued as rs1281214893; called by mutect2, pindel, varscan2
- AJM1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs992151258; called by muse, mutect2, varscan2
- AJM1 | c.1820G>A p.G607D | Missense Mutation (SNP) | VAF 75/339 reads (22%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.862); catalogued as rs1174082620; called by muse, mutect2, varscan2
- AKAP8L | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 97/540 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777700296; called by muse, mutect2, varscan2
- AKAP9 | c.5734C>T p.R1912C (on ENST00000359028; = p.R1880C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as rs761946454, COSV62342900; called by muse, mutect2, varscan2
- AKT1 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 90/433 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1457484217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH2 | c.1467del p.S490Vfs*16 | Frame Shift Del (DEL) | VAF 65/351 reads (19%) | catalogued as COSV99922810; called by mutect2, pindel, varscan2
- ALOX12B | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 88/419 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559401066, COSV59874094; called by muse, mutect2, varscan2
- ALOX12B | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 51/311 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs561140227, COSV59872136; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALS2CL | c.850A>G p.T284A | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs148624534; called by muse, mutect2, varscan2
- AMFR | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372095095; called by muse, mutect2, varscan2
- AMMECR1 | c.246del p.I83Sfs*80 | Frame Shift Del (DEL) | VAF 108/582 reads (19%) | catalogued as rs1179112821; called by mutect2, pindel, varscan2
- ANKRD20A1 | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs1296524808; called by mutect2, varscan2
- ANKRD31 | c.1533del p.G512Vfs*20 | Frame Shift Del (DEL) | VAF 56/276 reads (20%) | catalogued as rs1279723268; called by mutect2, pindel, varscan2
- ANKS3 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 98/420 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100423022; called by muse, mutect2, varscan2
- ANO9 | c.1031T>C p.M344T | Missense Mutation (SNP) | VAF 84/376 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs1323713029; called by muse, mutect2, varscan2
- AP1G2 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs374762900; called by muse, mutect2, varscan2
- APBA2 | c.1858T>C p.S620P | Missense Mutation (SNP) | VAF 117/542 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101258147; called by muse, mutect2, varscan2
- APEH | c.271dup p.E91Gfs*56 | Frame Shift Ins (INS) | VAF 41/216 reads (19%) | catalogued as rs768800917; called by mutect2, pindel, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 63/245 reads (26%) | catalogued as rs546686089; called by mutect2, varscan2
- APOBEC3G | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 69/375 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs375494335; called by muse, mutect2, varscan2
- ARAP2 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 63/405 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs749795521, COSV58283421; called by muse, mutect2, varscan2
- ARAP3 | c.2554C>T p.R852W | Missense Mutation (SNP) | VAF 74/373 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs749953827; called by muse, mutect2, varscan2
- ARHGAP28 | c.1065del p.F355Lfs*8 (on ENST00000383472 / NM_001366230.1; = p.F196Lfs*8 on NM_001010000.3) | Frame Shift Del (DEL) | VAF 59/328 reads (18%) | catalogued as rs1567977926, COSV51634082; called by mutect2, varscan2
- ARHGAP39 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 115/774 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs369180270; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 102/433 reads (24%) | catalogued as COSV61389445; called by mutect2, varscan2
- ARID5A | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 137/568 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs374390790; called by muse, mutect2, varscan2
- ARNTL | c.1820T>C p.L607S (on ENST00000403290 / NM_001297719.2; = p.L606S on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/358 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770550033; called by muse, mutect2, varscan2
- ASB18 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 102/519 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as rs894411374, COSV58234385; called by muse, mutect2, varscan2
- ASPHD2 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 48/416 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs781486947, COSV53218658; called by muse, mutect2, varscan2
- ASTN2 | c.3272A>G p.Q1091R (on ENST00000313400 / NM_001365069.1; = p.Q1040R on NM_014010.5) | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs529034532; called by muse, varscan2
- ATG2A | c.5780A>G p.H1927R | Missense Mutation (SNP) | VAF 22/483 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV63475492; called by muse, mutect2
- ATG2B | c.1593G>T p.Q531H | Missense Mutation (SNP) | VAF 20/431 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63423891; called by muse, mutect2
- ATP10A | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 87/495 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs745644823, COSV63519491; called by muse, mutect2, varscan2
- ATP10A | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as rs781555355, COSV63523354, COSV63525843; called by muse, varscan2
- ATP11A | c.2906C>T p.T969M | Missense Mutation (SNP) | VAF 88/386 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs747297211; called by muse, mutect2, varscan2
- ATP4A | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 67/337 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV52872258; called by muse, mutect2, varscan2
- ATP6V1FNB | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs1328786528; called by muse, mutect2, varscan2
- B3GNT6 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 106/558 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as rs782597921; called by muse, mutect2, varscan2
- BACH2 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 100/455 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as rs746829056, COSV57590630; called by muse, mutect2, varscan2
- BCHE | c.401dup p.N134Kfs*24 | Frame Shift Ins (INS) | VAF 54/305 reads (18%) | catalogued as rs764588882; called by mutect2, varscan2
- BCL11B | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 31/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs778308976, COSV100595875; called by muse, mutect2
- BCL2 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV61373565, COSV61374031, COSV61383113; called by muse, varscan2
- BCL6 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 85/414 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs746850741, COSV51651515; called by muse, mutect2, varscan2
- BEAN1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 161/353 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as rs747973755; called by muse, mutect2, varscan2
- BMP3 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 75/382 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as rs773959994; called by muse, mutect2, varscan2
- BNC1 | c.225dup p.M76Hfs*17 | Frame Shift Ins (INS) | VAF 37/239 reads (15%) | catalogued as rs751941533; called by mutect2, varscan2
- BRD2 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 118/637 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV66373242; called by muse, mutect2, varscan2
- BSX | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 88/468 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1565347536, COSV58005447; called by muse, mutect2, varscan2
- BTBD18 | c.1664C>T p.T555I | Missense Mutation (SNP) | VAF 18/490 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.221); catalogued as COSV99559945; called by muse, mutect2
- BTBD7 | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 100/447 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs757118592; called by muse, mutect2, varscan2
- BTBD9 | c.1738G>A p.G580S | Missense Mutation (SNP) | VAF 90/506 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs1345836943, COSV58424020; called by muse, mutect2, varscan2
- C12orf40 | c.557dup p.Q187Afs*3 | Frame Shift Ins (INS) | VAF 44/194 reads (23%) | catalogued as rs1276687036; called by mutect2, varscan2
- C14orf119 | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 17/458 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52972814; called by muse, mutect2
- C14orf39 | c.1762del p.*588Efs*16 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | catalogued as rs780875081; called by mutect2, varscan2
- C16orf54 | c.486del p.A163Pfs*5 | Frame Shift Del (DEL) | VAF 77/636 reads (12%) | catalogued as rs779355314; called by mutect2, pindel, varscan2
- C17orf97 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 28/583 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782199023; called by muse, mutect2
- C2CD4C | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 145/576 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.135); catalogued as rs777483787; called by muse, mutect2, varscan2
- C2orf78 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 69/408 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as rs756767934, COSV101280987, COSV68518293; called by muse, mutect2, varscan2
- C3AR1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs371493019; called by muse, mutect2, varscan2
- CA1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 40/341 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.185); catalogued as rs1395135419, COSV56279318; called by muse, mutect2, varscan2
- CACNA1C | c.4625G>A p.R1542H | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs771053661, COSV59749494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1D | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 68/349 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs533046755, COSV55456930, COSV55467087; called by muse, varscan2
- CACNA1E | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV62431441; called by muse, mutect2, varscan2
- CACNA1G | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs1254989551, COSV100661874; called by muse, mutect2, varscan2
- CACNA1H | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 75/326 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs200483658; called by muse, mutect2, varscan2
- CALML4 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.228); catalogued as rs751371702, COSV100682904; called by muse, mutect2, varscan2
- CAPN1 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 62/290 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54200118; called by muse, mutect2, varscan2
- CAPN10 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 44/556 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as rs1180541746; called by muse, mutect2
- CARD14 | c.2938G>A p.G980S | Missense Mutation (SNP) | VAF 100/532 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750872801, COSV58338347, COSV58339326; called by muse, mutect2, varscan2
- CASKIN2 | c.1016del p.P339Rfs*95 | Frame Shift Del (DEL) | VAF 70/446 reads (16%) | catalogued as COSV100050703; called by mutect2, varscan2
- CBWD1 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 24/456 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs1563789624; called by muse, mutect2
- CCAR2 | c.1249dup p.R417Pfs*49 | Frame Shift Ins (INS) | VAF 66/374 reads (18%) | catalogued as rs756536005; called by mutect2, varscan2
- CCDC175 | c.642dup p.C215Mfs*28 | Frame Shift Ins (INS) | VAF 38/302 reads (13%) | catalogued as rs760464505; called by mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 142/362 reads (39%) | catalogued as rs759258977; called by mutect2, varscan2
- CCL4L2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 55/312 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1314447954; called by muse, mutect2, varscan2
- CCN1 | c.1088A>G p.N363S | Missense Mutation (SNP) | VAF 23/472 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1300070540; called by muse, mutect2
- CCR2 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.084); catalogued as COSV52750349; called by muse, mutect2
- CD163L1 | c.1939C>T p.L647F | Missense Mutation (SNP) | VAF 20/426 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as COSV100550342, COSV58020178; called by muse, mutect2
- CD28 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.586); catalogued as rs201909740; called by muse, mutect2, varscan2
- CDAN1 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 78/355 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62332624; called by muse, mutect2, varscan2
- CDC40 | c.1502T>A p.I501N | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs376777025, COSV57009608; called by muse, mutect2, varscan2
- CDH1 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 120/517 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs746464544, COSV55737603; called by muse, mutect2, varscan2
- CDH13 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 94/253 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs371659407; called by muse, mutect2, varscan2
- CELF5 | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 91/456 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as COSV99485982; called by muse, mutect2, varscan2
- CELSR1 | c.3512C>T p.P1171L | Missense Mutation (SNP) | VAF 94/466 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1297948385, COSV99419150; called by muse, mutect2, varscan2
- CELSR2 | c.538del p.Q180Sfs*24 | Frame Shift Del (DEL) | VAF 114/456 reads (25%) | catalogued as COSV54781044; called by mutect2, varscan2
- CELSR2 | c.7102C>T p.R2368W | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780226633, COSV54778718; called by muse, mutect2, varscan2
- CENPM | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 105/431 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs371185369; called by muse, mutect2, varscan2
- CFAP52 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 55/343 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs779966953, COSV53307655; called by muse, mutect2, varscan2
- CFAP54 | c.7328T>G p.L2443R | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61575244; called by muse, mutect2, varscan2
- CHAMP1 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 17/366 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs782149634, COSV63522582; called by muse, mutect2
- CHRM4 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 110/453 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1247534212, COSV63127569; called by muse, mutect2, varscan2
- CHRNB1 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs371142002; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST4 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 115/535 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768338660, COSV58296873; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 28/140 reads (20%) | catalogued as rs752250702; called by mutect2, varscan2
- CKB | c.192G>A p.P64= | Splice Region (SNP) | VAF 22/315 reads (7%) | catalogued as COSV62379735; called by muse, mutect2
- CLASRP | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.988); catalogued as rs757672010; called by muse, mutect2, varscan2
- CLDN2 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 69/377 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV61021449; called by muse, mutect2, varscan2
- CLIC4 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs144375143; called by muse, mutect2, varscan2
- CLUH | c.3262G>A p.A1088T (on ENST00000435359; = p.A1127T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/462 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs747122833, COSV101425659, COSV70927633; called by muse, mutect2, varscan2
- CNTROB | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 82/322 reads (25%) | catalogued as rs780789745, COSV66607662; called by muse, mutect2, varscan2
- COL12A1 | c.9071G>C p.G3024A | Missense Mutation (SNP) | VAF 79/443 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59401173; called by muse, mutect2, varscan2
- COL22A1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 110/723 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs753278763, COSV57328854; called by muse, mutect2, varscan2
- COL25A1 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 96/576 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs1485385239, COSV67649797; called by muse, mutect2, varscan2
- COL27A1 | c.5413G>A p.E1805K | Missense Mutation (SNP) | VAF 57/307 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.278); catalogued as rs758079877, COSV100621044; called by muse, mutect2, varscan2
- COL6A3 | c.6826G>A p.G2276R | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761156771, COSV55081860; called by muse, mutect2, varscan2
- COMMD6 | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 60/263 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1022311434; called by muse, mutect2, varscan2
- CORO7 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 85/391 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs150670238; called by muse, mutect2, varscan2
- CPA1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 56/338 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782248213; called by muse, mutect2, varscan2
- CPT1C | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs961177119; called by muse, mutect2, varscan2
- CRACDL | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 110/574 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1293975643, COSV67408702; called by muse, varscan2
- CRB2 | c.3088del p.R1030Gfs*111 | Frame Shift Del (DEL) | VAF 101/627 reads (16%) | catalogued as rs1423457279; called by mutect2, pindel, varscan2
- CRTC2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs752412661; called by muse, mutect2, varscan2
- CRYBB1 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 46/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1000106932, COSV53232788, COSV99316145; called by muse, mutect2, varscan2
- CRYBG2 | c.746del p.P249Lfs*26 | Frame Shift Del (DEL) | VAF 102/450 reads (23%) | catalogued as rs969746389; called by mutect2, varscan2
- CSF2RB | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 110/615 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1449386315; called by muse, mutect2, varscan2
- CSMD1 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68203443, COSV68254018, COSV68261658; called by muse, mutect2, varscan2
- CSMD3 | c.3517A>G p.T1173A (on ENST00000297405 / NM_001363185.1; = p.T1069A on NM_052900.3) | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV52219329; called by muse, mutect2, varscan2
- CSPG5 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 106/444 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774101025; called by muse, varscan2
- CTIF | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 72/407 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1347911458; called by muse, mutect2, varscan2
- CTNND1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 45/336 reads (13%) | catalogued as COSV62381991; called by muse, mutect2, varscan2
- CUX2 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 112/485 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as rs766521721, COSV99920856; called by muse, mutect2, varscan2
- CXXC5 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 104/473 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV56796025; called by muse, mutect2, varscan2
- CYTH3 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs764467386; called by muse, mutect2, varscan2
- DBH | c.1374G>A p.P458= | Splice Region (SNP) | VAF 39/508 reads (8%) | catalogued as rs755089513, COSV67549037, COSV67549260; called by muse, mutect2
- DCST1 | c.1327C>A p.P443T | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99793403; called by muse, mutect2, varscan2
- DDR1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 34/856 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61319709, COSV61323846; called by muse, mutect2
- DDX21 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 77/335 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs201590875, COSV62555169; called by muse, mutect2, varscan2
- DDX31 | c.887T>C p.M296T | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs761693653; called by muse, varscan2
- DDX54 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 108/496 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779703558, COSV58373931; called by muse, mutect2, varscan2
- DENND3 | c.69dup p.R24Qfs*6 | Frame Shift Ins (INS) | VAF 156/933 reads (17%) | catalogued as rs752472767; called by mutect2, pindel, varscan2
- DEPTOR | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 87/659 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs140686348; called by muse, mutect2, varscan2
- DGKI | c.2115C>G p.S705R | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.677); catalogued as COSV99934690; called by muse, mutect2, varscan2
- DHX40 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 34/225 reads (15%) | catalogued as rs368453009, COSV52068189; called by muse, mutect2, varscan2
- DICER1 | c.2043T>C p.G681= | Splice Region (SNP) | VAF 48/261 reads (18%) | catalogued as rs1555371860; ClinVar: likely benign; called by muse, mutect2, varscan2
- DIDO1 | c.6619C>T p.R2207W | Missense Mutation (SNP) | VAF 99/494 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56628644; called by muse, varscan2
- DIDO1 | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459198190; called by muse, mutect2
- DIP2B | c.2992C>T p.R998* | Nonsense Mutation (SNP) | VAF 56/250 reads (22%) | catalogued as rs1171011310, COSV56585584; called by muse, mutect2, varscan2
- DIRAS1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs751412810; called by muse, mutect2, varscan2
- DIRAS1 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 107/466 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60216546; called by muse, varscan2
- DKK1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 46/303 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138015066; called by muse, mutect2, varscan2
- DLC1 | c.2162G>A p.G721D (on ENST00000276297 / NM_001348081.2; = p.G284D on NM_006094.5) | Missense Mutation (SNP) | VAF 26/502 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); catalogued as COSV52291906; called by muse, mutect2
- DLGAP4 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 59/367 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs542226781, COSV59422753, COSV59423221; called by muse, mutect2, varscan2
- DLGAP4 | c.2305G>A p.D769N (on ENST00000339266 / NM_001365621.1; = p.D766N on NM_014902.6) | Missense Mutation (SNP) | VAF 119/567 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs765504918; called by muse, mutect2, varscan2
- DNAAF3 | c.715G>A p.A239T (on ENST00000524407 / NM_001256715.2; = p.A286T on NM_178837.4) | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as rs886054641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH17 | c.5760G>T p.Q1920H | Missense Mutation (SNP) | VAF 63/282 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as rs777145501; called by muse, mutect2, varscan2
- DNAH3 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 94/402 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.782); catalogued as rs749966740; called by muse, mutect2
- DNAH7 | c.5651G>A p.R1884Q | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs201751336; called by muse, mutect2, varscan2
- DNAJC14 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 77/369 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs770661000; called by muse, mutect2, varscan2
- DNAJC8 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV99746365; called by muse, mutect2, varscan2
- DNER | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 65/352 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1255847009; called by muse, mutect2, varscan2
- DOCK10 | c.1122del p.D375Ifs*8 | Frame Shift Del (DEL) | VAF 40/204 reads (20%) | catalogued as rs750262341; called by mutect2, varscan2
- DOCK5 | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs891839673; called by muse, mutect2
- DOCK6 | c.3620C>T p.A1207V | Missense Mutation (SNP) | VAF 99/465 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as rs371021276, COSV53916328; called by muse, mutect2, varscan2
- DOP1B | c.3311C>T p.P1104L | Missense Mutation (SNP) | VAF 89/470 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs139832395; called by muse, mutect2, varscan2
- DTX3 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 117/519 reads (23%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.044); catalogued as rs1423428330; called by muse, mutect2, varscan2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 26/124 reads (21%) | catalogued as rs751377941; called by mutect2, varscan2
- DYRK1B | c.1633del p.Q545Sfs*19 | Frame Shift Del (DEL) | VAF 80/446 reads (18%) | catalogued as rs775499198; called by mutect2, pindel, varscan2
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 62/172 reads (36%) | catalogued as rs746509911; called by mutect2, varscan2
- EBI3 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 64/334 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as rs961736638; called by muse, mutect2, varscan2
- EDC4 | c.3740G>A p.R1247H | Missense Mutation (SNP) | VAF 110/519 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs774525692; called by muse, mutect2, varscan2
- EEPD1 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 85/467 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs746320616, COSV54196153; called by muse, mutect2, varscan2
- EIF2B3 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as rs373839928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF4E1B | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 51/311 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs750551455, COSV100024634; called by muse, mutect2, varscan2
- ELAVL3 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 105/435 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as rs748019175; called by muse, mutect2, varscan2
- ELFN1 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 112/586 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1463073712, COSV70035501; called by muse, mutect2, varscan2
- ELOA2 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 63/414 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.021); catalogued as rs1350477341, COSV55297602, COSV99796900; called by muse, mutect2, varscan2
- EMILIN1 | c.169A>G p.R57G | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV66695348; called by muse, mutect2, varscan2
- ENTHD1 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV57317352, COSV57317614; called by muse, mutect2
- EPPK1 | c.2764G>A p.V922I | Missense Mutation (SNP) | VAF 22/754 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs782597857, COSV73260828; called by muse, mutect2
- EPPK1 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 157/1068 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372469616; called by muse, mutect2, varscan2
- ERAP1 | c.2819G>A p.R940H (on ENST00000443439 / NM_001198541.2; = p.X940_splice on NM_016442.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); catalogued as rs111774449; called by muse, mutect2, varscan2
- ERBB3 | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 84/410 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403278713, COSV57247278, COSV57260257; called by muse, mutect2, varscan2
- ESPN | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 34/606 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1431421971; called by muse, mutect2
- ESRRB | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 63/295 reads (21%) | catalogued as rs1413130581, COSV55065231; called by muse, mutect2, varscan2
- EVC2 | c.3554G>A p.R1185Q | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.121); catalogued as rs772517447; called by muse, mutect2, varscan2
- EVC2 | c.2380del p.E794Rfs*13 | Frame Shift Del (DEL) | VAF 92/478 reads (19%) | catalogued as COSV100186376; called by mutect2, pindel, varscan2
- EVI2B | c.593del p.N198Tfs*6 | Frame Shift Del (DEL) | VAF 57/345 reads (17%) | catalogued as rs765136869; called by mutect2, pindel, varscan2
- EXOC3 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 19/466 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1385809761; called by muse, mutect2
- EXT1 | c.659G>A p.S220N | Missense Mutation (SNP) | VAF 75/496 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM099148; called by muse, mutect2, varscan2
- FADS6 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 145/614 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs1343258903; called by muse, mutect2, varscan2
- FAM13B | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs375120542; called by muse, mutect2, varscan2
- FAM13B | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 63/387 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs775718846, COSV50365761; called by muse, mutect2, varscan2
- FAM189A1 | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 113/436 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs933595813; called by muse, mutect2, varscan2
- FAM193B | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 116/536 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); catalogued as COSV61559269; called by muse, mutect2, varscan2
- FAM47A | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 128/616 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs368188314, COSV60496012, COSV60498636; called by muse, mutect2, varscan2
- FAM50B | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 182/440 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs369953711; called by muse, mutect2, varscan2
- FAM53A | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 103/574 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs199989747; called by muse, mutect2, varscan2
- FAM71B | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 85/373 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs751570900, COSV57228090; called by muse, mutect2, varscan2
- FAM78B | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 106/479 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV57979765; called by muse, mutect2, varscan2
- FARP1 | c.211A>G p.N71D | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.675); catalogued as rs764285227; called by muse, mutect2, varscan2
- FAT4 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 76/432 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV67887414; called by muse, mutect2, varscan2
- FBLN2 | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 50/526 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.65); catalogued as rs756221560; called by muse, mutect2
- FBN3 | c.1803del p.L602Wfs*3 | Frame Shift Del (DEL) | VAF 98/588 reads (17%) | catalogued as rs772353703; called by mutect2, pindel, varscan2
- FBRS | c.919C>T p.R307W (on ENST00000287468; = p.R827W on NM_001105079.3) | Missense Mutation (SNP) | VAF 123/554 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs775783751; called by muse, varscan2
- FBXL13 | c.357dup p.W120Mfs*4 | Frame Shift Ins (INS) | VAF 48/255 reads (19%) | catalogued as rs779744290; called by mutect2, pindel, varscan2
- FBXO17 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 112/487 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1378719530; called by muse, mutect2, varscan2
- FCGRT | c.320del p.G107Efs*29 | Frame Shift Del (DEL) | VAF 59/317 reads (19%) | catalogued as rs1568698688; called by mutect2, pindel, varscan2
- FCRL6 | c.999G>T p.W333C | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV58942915; called by muse, mutect2, varscan2
- FDXR | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 65/353 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772347757, COSV53120117; called by muse, mutect2, varscan2
- FER1L6 | c.2444del p.P815Hfs*14 | Frame Shift Del (DEL) | VAF 50/399 reads (13%) | catalogued as COSV67551700; called by mutect2, pindel, varscan2
- FGF5 | c.441del p.G148Efs*45 | Frame Shift Del (DEL) | VAF 42/215 reads (20%) | catalogued as rs35667286; called by mutect2, pindel, varscan2
- FHDC1 | c.1315del p.T439Pfs*2 | Frame Shift Del (DEL) | VAF 78/381 reads (20%) | catalogued as rs1303890230; called by mutect2, pindel, varscan2
- FLG2 | c.5323G>T p.G1775C | Missense Mutation (SNP) | VAF 80/404 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); catalogued as COSV66170424; called by muse, mutect2, varscan2
- FLNA | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 93/501 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs782702517; called by muse, mutect2, varscan2
- FLNC | c.4424C>T p.A1475V | Missense Mutation (SNP) | VAF 73/432 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369305865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT2 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 77/406 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs149005998; called by muse, mutect2, varscan2
- FLRT3 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 72/381 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.147); catalogued as COSV99430127; called by muse, mutect2, varscan2
- FMN1 | c.4228C>T p.R1410C (on ENST00000616417 / NM_001277313.2; = p.R1187C on NM_001103184.4) | Missense Mutation (SNP) | VAF 81/308 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as rs866300506, COSV57929513; called by muse, mutect2, varscan2
- FMN2 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 128/547 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV100142594; called by muse, mutect2, varscan2
- FMNL3 | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs200453321; called by muse, mutect2
- FNDC1 | c.2389G>A p.G797S | Missense Mutation (SNP) | VAF 87/474 reads (18%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs1175457226, COSV99796543; called by muse, mutect2, varscan2
- FNDC7 | c.1927G>A p.G643S | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.999); catalogued as COSV54756517; called by muse, mutect2
- FOXK1 | c.1643del p.G548Afs*63 | Frame Shift Del (DEL) | VAF 112/498 reads (22%) | catalogued as COSV61064449; called by mutect2, varscan2
- FSD2 | c.1646del p.G549Afs*4 | Frame Shift Del (DEL) | VAF 68/343 reads (20%) | catalogued as rs1246402267; called by mutect2, pindel, varscan2
- FSIP2 | c.20552T>C p.L6851P | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV58079092; called by muse, mutect2, varscan2
- FUT10 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 76/362 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs907194110, COSV59454006; called by muse, mutect2, varscan2
- FYCO1 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 39/572 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs752338309; called by muse, mutect2
- GABRA6 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 78/457 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs761702862, COSV50883828, COSV99194556; called by muse, mutect2, varscan2
- GAD1 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 73/304 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.619); catalogued as COSV64027046; called by muse, mutect2, varscan2
- GAL3ST1 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 89/419 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58893499; called by muse, mutect2, varscan2
- GALNT18 | c.1565C>T p.T522I | Missense Mutation (SNP) | VAF 73/357 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV57159107; called by muse, mutect2, varscan2
- GATAD2A | c.1094del p.P365Hfs*9 | Frame Shift Del (DEL) | VAF 103/490 reads (21%) | catalogued as rs35804366; called by mutect2, pindel, varscan2
- GBP4 | c.1237A>C p.N413H | Missense Mutation (SNP) | VAF 72/397 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765045127; called by muse, mutect2, varscan2
- GDF6 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 96/819 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs781041300; called by muse, mutect2, varscan2
- GNB2 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 95/463 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.063); catalogued as rs771355621; called by muse, mutect2, varscan2
- GNB3 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.336); catalogued as rs1268745886; called by muse, mutect2
- GNB4 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs751400013; called by muse, mutect2, varscan2
- GNL3 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1284646076, COSV56478550; called by muse, mutect2, varscan2
- GOLGA6L7 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 104/990 reads (11%) | SIFT tolerated (0.11); catalogued as rs1302672174, COSV73709768; called by muse, varscan2
- GOLGA7B | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 107/482 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.384); catalogued as rs776814365; called by muse, mutect2, varscan2
- GOSR2 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 102/402 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1179731044; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 44/216 reads (20%) | catalogued as rs370114090; called by mutect2, varscan2
- GPR182 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 111/477 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs780142167; called by muse, mutect2, varscan2
- GPR27 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 74/441 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.107); catalogued as rs373590635; called by muse, mutect2, varscan2
- GRB2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 57/271 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as rs1487234599, COSV57307677; called by muse, mutect2, varscan2
- GRID2 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 52/279 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774894054, COSV56243036; called by muse, mutect2, varscan2
- GRIN3B | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 113/512 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs1187425794; called by muse, mutect2, varscan2
- GRM5 | c.1248G>A p.M416I | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs750442341; called by muse, mutect2, varscan2
- GTPBP6 | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 53/530 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs748779841, COSV58206042; called by muse, mutect2
- GUCY2D | c.144del p.A49Pfs*36 | Frame Shift Del (DEL) | VAF 118/636 reads (19%) | catalogued as rs1567956946; called by mutect2, pindel, varscan2
- H1-1 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 169/413 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1182037965, COSV55118693; called by muse, mutect2, varscan2
- H2AC14 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 94/311 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.967); catalogued as rs771932401; called by muse, mutect2, varscan2
- H3-5 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 111/509 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as rs768639345, COSV61187308, COSV61187612; called by muse, mutect2, varscan2
- HAS1 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 43/646 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0.01); catalogued as rs975764736; called by muse, mutect2
- HAUS5 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs750857946; called by muse, mutect2, varscan2
- HCCS | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV58238810, COSV58239606; called by muse, mutect2, varscan2
- HDGFL1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 248/613 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.094); catalogued as rs1413674258, COSV100014505; called by muse, varscan2
- HEATR6 | c.1311del p.V438Ffs*24 | Frame Shift Del (DEL) | VAF 63/324 reads (19%) | catalogued as rs748699945, COSV51743560; called by mutect2, varscan2
- HECTD3 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1437957319, COSV55801750; called by muse, mutect2, varscan2
- HECW1 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 61/317 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs937673232; called by muse, mutect2, varscan2
- HECW2 | c.3301C>T p.R1101C | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1379141769, COSV53650660; called by muse, mutect2, varscan2
- HIC1 | c.145G>A p.V49M (on ENST00000322941 / NM_001098202.1; = p.V30M on NM_006497.4) | Missense Mutation (SNP) | VAF 121/513 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53969085; called by muse, mutect2, varscan2
- HOMER3 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 76/428 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99651100; called by muse, mutect2, varscan2
- HOXB8 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1302959869; called by muse, varscan2
- HSD17B4 | c.878C>T p.A293V (on ENST00000414835 / NM_001199291.3; = p.A268V on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.054); catalogued as rs1561458037; ClinVar: uncertain significance; called by muse, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 54/284 reads (19%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HTR7 | c.1421del p.K474Rfs*3 (on ENST00000336152 / NM_019859.4; = p.G442Vfs*6 on NM_000872.5) | Frame Shift Del (DEL) | VAF 44/218 reads (20%) | catalogued as COSV53287248; called by pindel, varscan2
- IARS1 | c.2992C>T p.R998C | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs746626200, COSV65113287; called by muse, mutect2, varscan2
- IDH2 | c.435del p.T146Lfs*15 | Frame Shift Del (DEL) | VAF 85/419 reads (20%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IFNA8 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 52/228 reads (23%) | catalogued as rs377683966, COSV66505054; called by muse, mutect2, varscan2
- IFT172 | c.2571G>T p.E857D | Missense Mutation (SNP) | VAF 55/340 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53131568; called by muse, mutect2, varscan2
- IGDCC4 | c.2613dup p.T872Hfs*22 | Frame Shift Ins (INS) | VAF 80/432 reads (19%) | catalogued as rs761621429; called by mutect2, varscan2
- IGHMBP2 | c.2404C>A p.P802T | Missense Mutation (SNP) | VAF 139/559 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV54822044; called by muse, mutect2, varscan2
- IGLV8-61 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs770175273, COSV66503109; called by muse, mutect2, varscan2
- IL17RD | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 68/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs534280278; called by muse, mutect2, varscan2
- IL21 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 61/348 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1216808032, COSV52645407, COSV99144440; called by muse, mutect2, varscan2
- ILK | c.989A>G p.D330G | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as rs1397320741; called by muse, mutect2, varscan2
- INO80 | c.3841C>T p.R1281W | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1482292423, COSV62736759; called by muse, mutect2, varscan2
- INO80E | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 88/425 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV58751334; called by muse, varscan2
- INPP5F | c.631dup p.W211Lfs*3 | Frame Shift Ins (INS) | VAF 51/261 reads (20%) | catalogued as rs768918635; called by mutect2, varscan2
- INSYN2B | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 80/433 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs551914094, COSV56943041; called by muse, mutect2, varscan2
- IQANK1 | c.853A>G p.M285V | Missense Mutation (SNP) | VAF 108/665 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs782170662; called by muse, mutect2, varscan2
- IRF8 | c.555C>T p.G185= | Splice Region (SNP) | VAF 90/329 reads (27%) | catalogued as rs761395039, COSV99236372; called by muse, mutect2, varscan2
- IRS1 | c.3362C>T p.A1121V | Missense Mutation (SNP) | VAF 100/497 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.062); catalogued as rs143913301; called by muse, mutect2, varscan2
- ITGA10 | c.241del p.A81Pfs*11 | Frame Shift Del (DEL) | VAF 73/446 reads (16%) | catalogued as rs782249120, COSV65196144, COSV65198308; called by mutect2, pindel, varscan2
- ITGAL | c.2474dup p.L827Tfs*13 | Frame Shift Ins (INS) | VAF 58/276 reads (21%) | catalogued as rs1349137502; called by mutect2, pindel, varscan2
- ITGAX | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 83/447 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs758064848, COSV51644385; called by muse, mutect2, varscan2
- ITIH5 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 58/344 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as rs1247790056, COSV56906234; called by muse, mutect2, varscan2
- ITPR3 | c.6139C>T p.R2047C | Missense Mutation (SNP) | VAF 68/322 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs760282940, COSV65407691; called by muse, mutect2, varscan2
- JAKMIP3 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371348426; called by muse, mutect2, varscan2
- JAKMIP3 | c.1537C>T p.Q513* | Nonsense Mutation (SNP) | VAF 22/394 reads (6%) | catalogued as COSV53825794; called by muse, mutect2
- JPH2 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 119/599 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs543276833; called by muse, mutect2, varscan2
- KALRN | c.2921C>T p.A974V | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.087); catalogued as COSV99566730; called by muse, varscan2
- KCNB2 | c.20del p.P7Rfs*3 | Frame Shift Del (DEL) | VAF 47/362 reads (13%) | catalogued as COSV73049036; called by mutect2, pindel, varscan2
- KCNE4 | c.397del p.E133Rfs*3 | Frame Shift Del (DEL) | VAF 90/475 reads (19%) | catalogued as rs760505003; called by mutect2, pindel, varscan2
- KCNG2 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 73/399 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs768056774; called by muse, mutect2, varscan2
- KCNG2 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 27/633 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV60269949; called by muse, mutect2
- KCNQ1 | c.1131C>T p.T377= | Splice Region (SNP) | VAF 46/232 reads (20%) | catalogued as rs763723387; called by muse, varscan2
- KCNQ3 | c.56del p.G19Afs*75 | Frame Shift Del (DEL) | VAF 25/284 reads (9%) | catalogued as rs1488204771; called by mutect2, pindel
- KCNS2 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 85/524 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54637276; called by muse, mutect2, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 93/454 reads (20%) | catalogued as rs754600318; called by mutect2, pindel, varscan2
- KCTD8 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 34/514 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as rs1446668885; called by muse, mutect2
- KIAA1109 | c.9268C>T p.R3090C | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV52692914; called by muse, mutect2, varscan2
- KIAA1614 | c.149del p.P50Qfs*15 | Frame Shift Del (DEL) | VAF 66/449 reads (15%) | catalogued as rs771572430; called by mutect2, pindel, varscan2
- KIF13B | c.5194G>A p.G1732S | Missense Mutation (SNP) | VAF 63/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1246146756; called by muse, mutect2, varscan2
- KIF16B | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758327212; called by muse, mutect2, varscan2
- KIF17 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 70/361 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs371219583, COSV56118638; called by muse, mutect2, varscan2
- KIF21B | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 40/229 reads (17%) | catalogued as rs765914389; called by muse, mutect2, varscan2
- KIF21B | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 20/492 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1391879484; called by muse, mutect2
- KIF2B | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs764658737, COSV52131068; called by muse, mutect2, varscan2
- KIR2DS4 | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 73/383 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.976); catalogued as rs372124222; called by muse, mutect2, varscan2
- KLB | c.2219T>C p.L740P | Missense Mutation (SNP) | VAF 114/533 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1415690570; called by muse, mutect2, varscan2
- KLF7 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 96/442 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs747043061; called by muse, varscan2
- KLHL41 | c.1296dup p.L433Tfs*9 | Frame Shift Ins (INS) | VAF 50/208 reads (24%) | catalogued as rs1288106608; called by mutect2, varscan2
- KLRF2 | c.178del p.M60Wfs*7 | Frame Shift Del (DEL) | VAF 35/230 reads (15%) | catalogued as rs781664453; called by mutect2, pindel, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 44/196 reads (22%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 70/335 reads (21%) | catalogued as COSV51456416; called by mutect2, pindel, varscan2
- KRT6C | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 29/425 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as rs755148780; called by muse, mutect2
- L3MBTL2 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 72/295 reads (24%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs201362426; called by muse, mutect2, varscan2
- LAMA1 | c.8248G>A p.G2750S | Missense Mutation (SNP) | VAF 69/338 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770312992; called by muse, mutect2, varscan2
- LAMA1 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs759093705; called by muse, varscan2
- LARGE1 | c.1802G>A p.R601H | Missense Mutation (SNP) | VAF 32/446 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as rs771376144; called by muse, mutect2
- LATS2 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 86/442 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1421513550, COSV66878098; called by muse, mutect2, varscan2
- LATS2 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 31/467 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1395329857, COSV66873669; called by muse, mutect2
- LDB3 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 66/297 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs727505129, COSV53939322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LEAP2 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs150053880; called by muse, mutect2, varscan2
- LEPROTL1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 87/412 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs550518450, COSV100260583; called by muse, mutect2, varscan2
- LHPP | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs373545055, COSV64328885; called by muse, mutect2
- LILRB5 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 69/392 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs111841445; called by muse, mutect2, varscan2
- LMO2 | c.209G>A p.R70H (on ENST00000395833 / NM_001142315.2; = p.R139H on NM_005574.4) | Missense Mutation (SNP) | VAF 61/381 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV99137911; called by muse, mutect2, varscan2
- LMOD2 | c.1443del p.K484Rfs*10 | Frame Shift Del (DEL) | VAF 78/416 reads (19%) | catalogued as COSV71755857; called by mutect2, pindel, varscan2
- LMOD3 | c.1427del p.P476Rfs*13 | Frame Shift Del (DEL) | VAF 101/471 reads (21%) | catalogued as COSV70456221; called by mutect2, pindel, varscan2
- LMTK3 | c.3650del p.P1217Lfs*99 | Frame Shift Del (DEL) | VAF 95/462 reads (21%) | catalogued as COSV54312443; called by mutect2, pindel, varscan2
- LOXHD1 | c.2986C>T p.R996C | Missense Mutation (SNP) | VAF 70/344 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746833881; called by muse, mutect2, varscan2
- LOXL2 | c.1020G>T p.E340D | Missense Mutation (SNP) | VAF 94/428 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1467086469; called by muse, mutect2, varscan2
- LRCH3 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 53/294 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs773238353; called by muse, mutect2, varscan2
- LRFN3 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 111/584 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs947789538, COSV99873513; called by muse, mutect2, varscan2
- LRP1 | c.10529C>T p.A3510V | Missense Mutation (SNP) | VAF 91/431 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.793); catalogued as rs543562619; called by muse, mutect2, varscan2
- LRP4 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV101066958; called by muse, mutect2, varscan2
- LRRC15 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 101/459 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs544084516; called by muse, mutect2, varscan2
- LRRC4B | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 111/570 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); catalogued as rs763207062, COSV65349197; called by muse, mutect2, varscan2
- LRRC52 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 90/451 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs752231121; called by muse, mutect2, varscan2
- LRRFIP1 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs764869813; called by muse, mutect2, varscan2
- LRRIQ1 | c.4053G>A p.M1351I | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1180438374; called by muse, varscan2
- LRRIQ3 | c.1395dup p.Y466Ifs*8 | Frame Shift Ins (INS) | VAF 45/257 reads (18%) | catalogued as rs1456074613; called by mutect2, pindel, varscan2
- LRRTM4 | c.1029G>T p.K343N | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV69138961; called by muse, mutect2, varscan2
- LTBP2 | c.4667del p.P1556Rfs*12 | Frame Shift Del (DEL) | VAF 84/462 reads (18%) | catalogued as COSV100000106; called by mutect2, pindel, varscan2
- LYPD3 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 94/481 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs746314355; called by muse, mutect2, varscan2
- LYSMD4 | c.151del p.R51Gfs*63 (on ENST00000409796 / NM_001284417.2; = p.A23Qfs*18 on NM_152449.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 83/491 reads (17%) | catalogued as COSV60387767; called by mutect2, pindel, varscan2
- LYST | c.9491C>A p.P3164H | Missense Mutation (SNP) | VAF 62/301 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67714368; called by muse, mutect2, varscan2
- LZTS3 | c.1762C>T p.R588W (on ENST00000329152; = p.R542W on NM_001282533.2) | Missense Mutation (SNP) | VAF 38/695 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99418385; called by muse, mutect2
- MAB21L1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 75/386 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59787960; called by muse, mutect2, varscan2
- MACROH2A2 | c.438dup p.K147Efs*21 | Frame Shift Ins (INS) | VAF 71/369 reads (19%) | catalogued as rs775088830; called by mutect2, varscan2
- MAGEL2 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 117/656 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100045654; called by muse, mutect2, varscan2
- MAGEL2 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 93/512 reads (18%) | SIFT deleterious, low confidence (0); catalogued as rs1317236335; called by muse, mutect2, varscan2
- MAP3K4 | c.1637T>C p.L546P | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62339047; called by muse, mutect2, varscan2
- MAPT | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); catalogued as rs762595428; called by muse, mutect2, varscan2
- MCM2 | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 99/400 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374686602; called by muse, mutect2, varscan2
- MDM2 | c.961dup p.L321Pfs*13 | Frame Shift Ins (INS) | VAF 56/288 reads (19%) | catalogued as rs746910913; called by mutect2, varscan2
- MED23 | c.396G>A p.K132= | Splice Region (SNP) | VAF 16/288 reads (6%) | catalogued as COSV63436776; called by muse, mutect2
- METTL24 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.652); catalogued as COSV58821481; called by muse, varscan2
- METTL24 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1406226686; called by muse, varscan2
- METTL2A | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777410698, COSV100274285; called by muse, mutect2, varscan2
- MFSD3 | c.968T>C p.L323P | Missense Mutation (SNP) | VAF 52/408 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1270569453; called by muse, mutect2, varscan2
- MIB1 | c.503A>G p.Q168R | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs768615092; called by muse, mutect2, varscan2
- MID2 | c.1787T>C p.V596A | Missense Mutation (SNP) | VAF 56/348 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.044); catalogued as rs754391185; called by muse, mutect2, varscan2
- MIDEAS | c.3126del p.K1042Nfs*51 | Frame Shift Del (DEL) | VAF 42/232 reads (18%) | catalogued as rs1168947806; called by mutect2, pindel, varscan2
- MNDA | c.164del p.K55Sfs*8 | Frame Shift Del (DEL) | VAF 78/367 reads (21%) | catalogued as rs750084919, COSV100933258; called by mutect2, pindel, varscan2
- MOB1B | c.567del p.F189Lfs*19 | Frame Shift Del (DEL) | VAF 28/190 reads (15%) | catalogued as rs778232663; called by mutect2, varscan2
- MPPE1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs553789724, COSV100013380; called by muse, mutect2, varscan2
- MROH7 | c.3356G>A p.R1119H | Missense Mutation (SNP) | VAF 96/493 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs370697369; called by muse, mutect2, varscan2
- MRPS11 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 74/379 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs868558983, COSV100363795; called by muse, mutect2, varscan2
- MSC | c.417del p.D140Tfs*37 | Frame Shift Del (DEL) | VAF 69/607 reads (11%) | catalogued as COSV57696108; called by mutect2, varscan2
- MTNR1A | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 77/379 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1204394455; called by muse, mutect2, varscan2
- MTRR | c.326C>T p.P109L (on ENST00000264668; = p.P82L on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/312 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs747303076, CM159483, COSV52945502; called by muse, mutect2, varscan2
- MUC12 | c.1964T>C p.M655T (on ENST00000379442; = p.M512T on NM_001164462.1) | Missense Mutation (SNP) | VAF 78/1200 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs775228023, COSV65207932; called by muse, mutect2
- MUC16 | c.38132A>G p.K12711R | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.005); catalogued as COSV101200549, COSV67468280; called by muse, mutect2, varscan2
- MUC6 | c.6601_6603del p.S2201del | In Frame Del (DEL) | VAF 123/614 reads (20%) | catalogued as rs1296850164; called by pindel, varscan2
- MUC6 | c.3313G>A p.V1105M | Missense Mutation (SNP) | VAF 125/630 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199855990; called by muse, mutect2, varscan2
- MYBL2 | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 57/364 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776972688, COSV53831326; called by muse, mutect2, varscan2
- MYBPC2 | c.2689T>C p.F897L | Missense Mutation (SNP) | VAF 32/594 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1016515765; called by muse, mutect2
- MYH2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99820661; called by muse, mutect2, varscan2
- MYO19 | c.2443C>T p.R815C (on ENST00000614623 / NM_001163735.1; = p.R615C on NM_025109.5) | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs966331392; called by muse, mutect2, varscan2
- MYOM2 | c.2881G>A p.V961M | Missense Mutation (SNP) | VAF 57/271 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs140995511; called by muse, mutect2, varscan2
- MYT1 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 111/562 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1224565423, COSV60505485; called by muse, mutect2, varscan2
- NAPEPLD | c.507del p.C170Afs*3 | Frame Shift Del (DEL) | VAF 96/550 reads (17%) | catalogued as COSV58521796; called by mutect2, pindel, varscan2
- NAT2 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764591879; called by muse, mutect2, varscan2
- NAT8L | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 39/517 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1292312324; called by muse, mutect2
- NBEA | c.5437G>A p.A1813T | Missense Mutation (SNP) | VAF 60/326 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100080616; called by muse, mutect2, varscan2
- NCAN | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 105/457 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV53050030; called by muse, mutect2, varscan2
- NCAPD3 | c.961dup p.L321Pfs*11 | Frame Shift Ins (INS) | VAF 73/411 reads (18%) | catalogued as rs1418614888; called by mutect2, pindel, varscan2
- NCEH1 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.022); catalogued as rs774718169; called by muse, mutect2
- NDE1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs147283674; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NDST1 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 101/451 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147230606; called by muse, mutect2, varscan2
- NELFCD | c.443_445del p.E148del (on ENST00000602795; = p.E130del on NM_198976.4) | In Frame Del (DEL) | VAF 36/208 reads (17%) | catalogued as rs760570495; called by pindel, varscan2
- NELL1 | c.1717T>C p.Y573H | Missense Mutation (SNP) | VAF 60/366 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs775432629; called by muse, mutect2, varscan2
- NEUROG1 | c.584del p.P195Rfs*56 | Frame Shift Del (DEL) | VAF 112/591 reads (19%) | catalogued as COSV59082395; called by mutect2, pindel, varscan2
- NFKBID | c.865C>T p.R289W (on ENST00000396901; = p.R441W on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/371 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs773657096, COSV61729046; called by muse, mutect2, varscan2
- NFKBIE | c.698C>T p.A233V (on ENST00000275015; = p.A94V on NM_004556.3) | Missense Mutation (SNP) | VAF 128/548 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV51490402; called by muse, mutect2, varscan2
- NFXL1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 109/508 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs921878096; called by muse, varscan2
- NGF | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 74/344 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327571056, COSV65688390; called by muse, mutect2, varscan2
- NGF | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 78/424 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as rs201087374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKD2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 104/372 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749745224, COSV99724197; called by muse, varscan2
- NLGN1 | c.1532A>G p.Y511C | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs982541422; called by muse, mutect2, varscan2
- NLGN4X | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52008771, COSV52025322; called by muse, mutect2, varscan2
- NLRC3 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 121/571 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs767905220, COSV100072851, COSV57095220; called by muse, mutect2, varscan2
- NLRP10 | c.824A>G p.H275R | Missense Mutation (SNP) | VAF 113/548 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs1344708334; called by muse, mutect2, varscan2
- NNAT | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 84/357 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV104379709; called by muse, mutect2, varscan2
- NOL6 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 76/308 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as rs370467883, COSV53041174; called by muse, mutect2, varscan2
- NOP53 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 92/440 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs991513152; called by muse, mutect2, varscan2
- NOTCH2 | c.5770G>T p.G1924C | Missense Mutation (SNP) | VAF 55/328 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56681632; called by muse, mutect2, varscan2
- NOX3 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 77/359 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs199928709, COSV50150378; called by muse, mutect2, varscan2
- NPAS3 | c.2693C>T p.P898L (on ENST00000356141 / NM_001164749.2; = p.P866L on NM_022123.3) | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs1365932385; called by muse, mutect2
- NPIPB15 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 230/1162 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.937); catalogued as rs1240794443; called by muse, mutect2, varscan2
- NR4A2 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 102/470 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.371); catalogued as COSV59893939; called by muse, mutect2, varscan2
- NRBP2 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 109/765 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782250042, COSV59918517; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 62/324 reads (19%) | catalogued as rs776154715; called by mutect2, varscan2
- NRK | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 25/572 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV54602655; called by muse, mutect2
- NRROS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 30/514 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1181456534, COSV60747963; called by muse, mutect2
- NSMCE1 | c.303dup p.A102Cfs*4 | Frame Shift Ins (INS) | VAF 63/363 reads (17%) | catalogued as rs1405472517; called by mutect2, pindel, varscan2
- NSMCE3 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 95/538 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.781); catalogued as rs1042783692; called by muse, mutect2, varscan2
- NUDT14 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 82/433 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs764223059, COSV59650378, COSV59650674; called by muse, mutect2, varscan2
- NUP214 | c.4930G>A p.V1644I | Missense Mutation (SNP) | VAF 103/421 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as rs370335340; called by muse, mutect2, varscan2
- NUP93 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 114/298 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750107617, COSV57432122; called by muse, mutect2, varscan2
- NUTM1 | c.1376_1378del p.E459del | In Frame Del (DEL) | VAF 38/198 reads (19%) | catalogued as rs754758926; called by pindel, varscan2
- OR10A2 | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.944); catalogued as COSV100225088; called by muse, mutect2, varscan2
- OR10D3 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs1014563561; called by muse, mutect2, varscan2
- OR13F1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs138205504; called by muse, mutect2, varscan2
- OR1K1 | c.821T>G p.V274G | Missense Mutation (SNP) | VAF 68/393 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99474383; called by muse, mutect2, varscan2
- OR2T12 | c.592T>C p.Y198H | Missense Mutation (SNP) | VAF 20/592 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100527962; called by muse, mutect2
- OR4C11 | c.779del p.P260Rfs*28 | Frame Shift Del (DEL) | VAF 93/384 reads (24%) | catalogued as rs764963140, COSV56352663, COSV56353360; called by mutect2, pindel, varscan2
- OR4K3 | c.812C>G p.S271C | Missense Mutation (SNP) | VAF 72/919 reads (8%) | catalogued as rs1016476088; called by muse, mutect2
- OR4K5 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 54/800 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs1184379733; called by muse, mutect2
- OSCP1 | c.452G>A p.R151Q (on ENST00000356637 / NM_001330493.1; = p.R141Q on NM_145047.5) | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs141201826; called by muse, mutect2, varscan2
- OTUD7B | c.366del p.S123Afs*29 | Frame Shift Del (DEL) | VAF 82/334 reads (25%) | catalogued as rs1553776851; called by mutect2, varscan2
- P4HA1 | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 25/390 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as rs781544054; called by muse, mutect2
- PABPC5 | c.110A>C p.K37T | Missense Mutation (SNP) | VAF 99/504 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV57041654, COSV57041670; called by muse, mutect2, varscan2
- PABPC5 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 99/490 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV100442529; called by muse, mutect2, varscan2
- PANX2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 87/485 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1313188842; called by muse, mutect2, varscan2
- PAPLN | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757660671, COSV99059741; called by muse, mutect2, varscan2
- PAPOLG | c.744G>T p.W248C | Missense Mutation (SNP) | VAF 76/364 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99474940; called by muse, mutect2, varscan2
- PAPPA | c.3793G>A p.V1265I | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs139138259, COSV60289403; called by muse, mutect2, varscan2
- PARD3B | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 65/335 reads (19%) | catalogued as rs773130577, COSV62502513; called by muse, mutect2, varscan2
- PARP14 | c.4244del p.K1415Rfs*35 | Frame Shift Del (DEL) | VAF 51/250 reads (20%) | catalogued as rs1205949740; called by mutect2, varscan2
- PATJ | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs746434448, COSV57167235; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 67/404 reads (17%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PCCA | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 60/325 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747943045, COSV66187867; called by muse, mutect2, varscan2
- PCDH15 | c.3580G>T p.G1194* | Nonsense Mutation (SNP) | VAF 43/232 reads (19%) | catalogued as COSV57316728, COSV57342928; called by muse, mutect2, varscan2
- PCDH15 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.572); catalogued as rs1564545545, COSV100213918, COSV100214304; called by muse, mutect2, varscan2
- PCDHA10 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 147/615 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs912006741; called by muse, mutect2, varscan2
- PCDHA2 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 126/614 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as rs782310227, COSV65367654, COSV65370923; called by muse, mutect2, varscan2
- PCDHAC2 | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 77/333 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs782055086, COSV53843864; called by muse, mutect2, varscan2
- PCDHB5 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 133/647 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs148772334; called by muse, mutect2, varscan2
- PCDHB9 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 98/535 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV53382763; called by muse, mutect2, varscan2
- PCDHGA2 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 86/385 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); catalogued as rs770199497, COSV53894862; called by muse, mutect2, varscan2
- PCDHGA2 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 51/395 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs999425469; called by muse, mutect2, varscan2
- PCF11 | c.1733G>A p.G578D | Missense Mutation (SNP) | VAF 67/285 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1231281058; called by muse, mutect2, varscan2
- PCNX3 | c.980del p.P327Qfs*104 | Frame Shift Del (DEL) | VAF 99/531 reads (19%) | catalogued as COSV58421170; called by mutect2, pindel, varscan2
- PCOLCE | c.1173del p.M392* | Frame Shift Del (DEL) | VAF 69/306 reads (23%) | catalogued as rs777844367; called by mutect2, pindel, varscan2
- PDCD6IP | c.602del p.L201* | Frame Shift Del (DEL) | VAF 54/258 reads (21%) | catalogued as rs781474699; called by mutect2, varscan2
- PDCL | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 63/285 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1427822305, COSV99414164, COSV99414165; called by muse, mutect2, varscan2
- PDE4DIP | c.5528T>G p.L1843R | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57700257; called by muse, mutect2, varscan2
- PDE6A | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 63/359 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as rs780279555, COSV54926586, COSV54931413; called by muse, mutect2, varscan2
- PEG3 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 63/295 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs151090043; called by muse, mutect2, varscan2
- PFKP | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 58/347 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66896529; called by muse, mutect2, varscan2
- PHF20L1 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.475); catalogued as rs1241313229, COSV55188691; called by muse, mutect2, varscan2
- PHOSPHO1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 113/546 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99865669; called by muse, varscan2
- PIGH | c.273A>T p.L91F | Missense Mutation (SNP) | VAF 94/395 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV53614894; called by muse, mutect2, varscan2
- PIGO | c.2959G>A p.E987K | Missense Mutation (SNP) | VAF 65/333 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.484); catalogued as rs550176742; called by muse, mutect2, varscan2
- PIK3AP1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1364487885, COSV59535082, COSV59537031; ClinVar: uncertain significance; called by muse, varscan2
- PIP5K1C | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 116/528 reads (22%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as rs1025824107; called by muse, mutect2, varscan2
- PITPNM3 | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 92/417 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs1238435519, COSV51470475; called by muse, mutect2, varscan2
- PITX3 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 80/398 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64174176; called by muse, mutect2, varscan2
- PKD1 | c.8324C>T p.T2775M | Missense Mutation (SNP) | VAF 124/536 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.742); catalogued as rs186826765; called by muse, mutect2, varscan2
- PKD1L3 | c.2221G>A p.A741T | Missense Mutation (SNP) | VAF 90/228 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs1019953806; called by muse, mutect2, varscan2
- PKDREJ | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 92/473 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs764375742, COSV53547490; called by muse, mutect2, varscan2
- PKHD1L1 | c.7573G>T p.A2525S | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV65749707, COSV65750639; called by muse, mutect2, varscan2
- PKLR | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 78/415 reads (19%) | catalogued as rs902988637, CM981577; called by muse, mutect2, varscan2
- PKP3 | c.1390del p.L464Sfs*183 | Frame Shift Del (DEL) | VAF 96/518 reads (19%) | catalogued as rs757594408; called by mutect2, pindel, varscan2
- PKP4 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs374838936; called by muse, mutect2, varscan2
- PLA2G15 | c.695dup p.V233Rfs*47 | Frame Shift Ins (INS) | VAF 132/304 reads (43%) | catalogued as rs763871300; called by mutect2, varscan2
- PLCB3 | c.1771T>C p.S591P | Missense Mutation (SNP) | VAF 69/306 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54185459; called by muse, mutect2, varscan2
- PLCB4 | c.3506G>A p.R1169H (on ENST00000278655 / NM_182797.3; = p.P1181= on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/317 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs533978785; called by muse, mutect2, varscan2
- PLEC | c.8002C>T p.R2668C (on ENST00000322810 / NM_201380.4; = p.R2558C on NM_000445.5) | Missense Mutation (SNP) | VAF 103/714 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.153); catalogued as rs781838363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.2023C>T p.R675C (on ENST00000322810 / NM_201380.4; = p.R565C on NM_000445.5) | Missense Mutation (SNP) | VAF 25/836 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs782678779, COSV100514295, COSV59676279; called by muse, mutect2
- PLEKHG4 | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 118/281 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs755431092, COSV58575214; called by muse, mutect2, varscan2
- PLEKHH1 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 72/314 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs763998194; called by muse, mutect2, varscan2
- PLPPR4 | c.2048G>A p.G683E | Missense Mutation (SNP) | VAF 55/315 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as rs770613751; called by muse, mutect2, varscan2
- PLXNA1 | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 103/573 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52532568; called by muse, mutect2, varscan2
- PLXNA2 | c.5039G>A p.R1680Q | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65444771; called by muse, mutect2, varscan2
- PLXNA3 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 116/560 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.409); catalogued as rs782812977; called by muse, varscan2
- PLXNA3 | c.3817G>T p.E1273* | Nonsense Mutation (SNP) | VAF 67/392 reads (17%) | catalogued as COSV100859824; called by muse, mutect2, varscan2
- PLXNB1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 100/531 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.657); catalogued as rs1181925738; called by muse, mutect2, varscan2
- PLXNB2 | c.4499G>A p.R1500H | Missense Mutation (SNP) | VAF 82/408 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1470249034, COSV100833843; called by muse, varscan2
- PLXNB3 | c.3005G>A p.R1002H | Missense Mutation (SNP) | VAF 132/639 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868912528, COSV100738036; ClinVar: not provided; called by muse, mutect2, varscan2
- PLXNB3 | c.4099C>T p.R1367C | Missense Mutation (SNP) | VAF 129/585 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs782068600, COSV62797349; called by muse, mutect2, varscan2
- PLXND1 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs760772408; called by muse, mutect2, varscan2
- PML | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 135/564 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV51450878; called by muse, mutect2, varscan2
- POLD1 | c.2788G>A p.A930T | Missense Mutation (SNP) | VAF 34/453 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.153); catalogued as rs144111108; ClinVar: uncertain significance; called by muse, mutect2
- POLQ | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs190592691; called by muse, mutect2, varscan2
- POLR1B | c.2405G>A p.R802H | Missense Mutation (SNP) | VAF 79/405 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.836); catalogued as rs559403620, COSV54495441; called by muse, mutect2, varscan2
- POLR2M | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 73/306 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs1213324079; called by muse, mutect2, varscan2
- PON1 | c.977_978del p.T326Sfs*28 | Frame Shift Del (DEL) | VAF 65/391 reads (17%) | catalogued as rs776442033; called by pindel, varscan2
- POR | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 73/363 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs781915397; called by muse, mutect2, varscan2
- POTEM | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 63/2132 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.952); catalogued as rs1423420665, COSV101304515; called by muse, mutect2
- PPM1N | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 69/759 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as rs761993103, COSV55595843; called by muse, mutect2
- PPM1N | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 44/620 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419657596, COSV55592798; called by muse, mutect2
- PPP3CA | c.913A>T p.I305F | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV59929464; called by muse, mutect2, varscan2
- PRC1 | c.1806G>T p.K602N | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV62695267; called by muse, mutect2, varscan2
- PRDM6 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 122/585 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.047); catalogued as rs1158382580; called by muse, mutect2, varscan2
- PRICKLE1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 67/361 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs1457774536, COSV61543203; called by muse, mutect2, varscan2
- PRKAR1A | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 47/298 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV62235601; called by muse, mutect2, varscan2
- PRKDC | c.5464C>T p.R1822C | Missense Mutation (SNP) | VAF 72/393 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377127342; called by muse, mutect2, varscan2
- PROC | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 70/424 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs764546127, CM950976, COSV52169140; called by muse, mutect2, varscan2
- PROSER3 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 30/594 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV56553416; called by muse, mutect2
- PROZ | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 37/255 reads (15%) | catalogued as rs762972727; called by muse, mutect2, varscan2
- PRPF40B | c.230C>T p.T77M (on ENST00000380281; = p.T71M on NM_012272.3) | Missense Mutation (SNP) | VAF 108/461 reads (23%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.586); catalogued as rs775090849, COSV56060238; called by muse, mutect2, varscan2
- PRPS1L1 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 82/445 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs755833483, COSV101552934; called by muse, mutect2, varscan2
- PRRC2C | c.1543C>T p.R515W (on ENST00000367742; = p.R513W on NM_015172.4) | Missense Mutation (SNP) | VAF 68/350 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.432); catalogued as rs964739989; called by muse, mutect2, varscan2
- PRRG3 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 109/614 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as rs768041636; called by muse, mutect2, varscan2
- PRRT4 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 151/638 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as rs1329282885; called by muse, varscan2
- PRSS36 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 77/421 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.981); catalogued as rs778876008, COSV51636717; called by muse, mutect2, varscan2
- PSAP | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs1313523627; called by muse, mutect2, varscan2
- PTGER1 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 126/549 reads (23%) | catalogued as rs1325890485; called by muse, mutect2, varscan2
- PTGS1 | c.381del p.T128Pfs*17 | Frame Shift Del (DEL) | VAF 77/375 reads (21%) | catalogued as rs779702921; called by mutect2, pindel, varscan2
- PTK2B | c.2709del p.E904Rfs*7 | Frame Shift Del (DEL) | VAF 50/378 reads (13%) | catalogued as rs869044240; called by mutect2, pindel, varscan2
- PTPN14 | c.177G>A p.T59= | Splice Region (SNP) | VAF 32/275 reads (12%) | catalogued as rs1412318782, COSV65284099; called by muse, mutect2, varscan2
- PTPN23 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 81/361 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs772232549; called by muse, mutect2, varscan2
- PTPRG | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 90/445 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs890069022; called by muse, mutect2, varscan2
- PTPRJ | c.3332C>T p.A1111V | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1378418093; called by muse, varscan2
- PTPRK | c.1731A>C p.K577N | Missense Mutation (SNP) | VAF 20/456 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100950591; called by muse, mutect2
- PTPRN2 | c.2098G>T p.G700W | Missense Mutation (SNP) | VAF 95/488 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756749450, COSV67054801; called by muse, mutect2, varscan2
- PTPRS | c.3072del p.V1025Sfs*18 | Frame Shift Del (DEL) | VAF 86/443 reads (19%) | catalogued as rs756013055, COSV53629833; called by mutect2, pindel, varscan2
- PTPRT | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61963341; called by muse, mutect2
- PZP | c.3899A>G p.N1300S | Missense Mutation (SNP) | VAF 62/346 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs760841953, COSV99738241; called by muse, mutect2, varscan2
- RAB39B | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 101/491 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV65624525; called by muse, mutect2, varscan2
- RAB3B | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 61/347 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs201157918; called by muse, mutect2, varscan2
- RAB40C | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445146734; called by muse, mutect2, varscan2
- RAB44 | c.830T>C p.L277P | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174702053; called by muse, mutect2, varscan2
- RAD52 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as rs751078161; called by muse, mutect2, varscan2
- RAD54B | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as rs764212601, COSV60250144; called by muse, mutect2, varscan2
- RASAL2 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 21/338 reads (6%) | catalogued as rs1433236647; called by muse, mutect2
- RBM15 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 83/405 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs539424286, COSV100873529; called by muse, mutect2, varscan2
- RBMXL3 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 143/576 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as rs782376039; called by muse, mutect2, varscan2
- RBP3 | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 99/459 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782530735; called by muse, mutect2, varscan2
- RBP4 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 85/399 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747468011, COSV65160280; called by muse, mutect2, varscan2
- RCOR2 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 63/341 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs746643156, COSV100036236; called by muse, mutect2, varscan2
- RCVRN | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as rs1394740092; called by muse, mutect2, varscan2
- REC114 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs780798070; called by muse, mutect2, varscan2
- RECQL4 | c.2129G>A p.R710H | Missense Mutation (SNP) | VAF 69/553 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs781121286, COSV52879699; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RELCH | c.2591G>A p.R864H | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as rs766145734, COSV56883989, COSV56884489; called by muse, mutect2, varscan2
- RELN | c.7088G>A p.R2363H | Missense Mutation (SNP) | VAF 67/314 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1562879117; called by muse, mutect2, varscan2
- RELT | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 133/640 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs1565223128, COSV50363279; called by muse, mutect2, varscan2
- RFXANK | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 55/371 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs769970316, COSV57395231; called by muse, mutect2, varscan2
- RGP1 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 94/469 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs769640992, COSV100960328; called by muse, mutect2, varscan2
- RGPD3 | c.3566C>T p.A1189V | Missense Mutation (SNP) | VAF 16/606 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1558840019; called by muse, mutect2
- RIMS1 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1355621402, COSV53485553; called by muse, mutect2, varscan2
- RIMS2 | c.2431C>T p.R811* (on ENST00000666250 / NM_001348490.2; = p.R619* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 68/475 reads (14%) | catalogued as rs951108608; called by muse, mutect2, varscan2
- RIMS3 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 99/430 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs368947805; called by muse, mutect2, varscan2
- RIN3 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1363627007, COSV53656735; called by muse, mutect2
- RNF112 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 78/375 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); catalogued as rs748210557, COSV71327055; called by muse, mutect2, varscan2
- RNF216 | c.2437C>T p.R813W (on ENST00000425013 / NM_207116.3; = p.R870W on NM_207111.4) | Missense Mutation (SNP) | VAF 120/560 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs1353027171, COSV66289721; called by muse, mutect2, varscan2
- RNF43 | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 86/471 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV101348400; called by muse, mutect2, varscan2
- RNF43 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs886926322, COSV68457519; called by muse, mutect2, varscan2
- ROBO1 | c.3643C>T p.P1215S | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs770906589, COSV71398697; called by muse, mutect2, varscan2
- RP1L1 | c.2087G>A p.C696Y | Missense Mutation (SNP) | VAF 80/468 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.575); catalogued as rs1415143880; called by muse, mutect2, varscan2
- RPLP0 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 63/319 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.04); catalogued as rs888835947; called by muse, mutect2, varscan2
- RPS6KL1 | c.1330del p.E444Rfs*18 | Frame Shift Del (DEL) | VAF 74/426 reads (17%) | catalogued as COSV100665298; called by mutect2, pindel, varscan2
- RRAD | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 84/461 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768941924; called by muse, mutect2, varscan2
- RREB1 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 174/462 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs753485408, COSV100619497; called by muse, mutect2, varscan2
- RTN1 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 112/553 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs753478557, COSV50718474; called by muse, mutect2, varscan2
- RTTN | c.3373G>A p.A1125T | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs183531175; called by muse, mutect2, varscan2
- RYR2 | c.1397del p.P466Qfs*5 | Frame Shift Del (DEL) | VAF 50/372 reads (13%) | catalogued as COSV100771204; called by mutect2, pindel, varscan2
- RYR2 | c.6744G>A p.M2248I | Missense Mutation (SNP) | VAF 60/349 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as rs1558107315; called by muse, mutect2, varscan2
- RYR3 | c.13123C>T p.R4375W (on ENST00000389232; = p.R4376W on NM_001036.6) | Missense Mutation (SNP) | VAF 78/388 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs753219318, COSV66788025; called by muse, mutect2, varscan2
- SACS | c.12952T>C p.W4318R | Missense Mutation (SNP) | VAF 75/379 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs762499265; called by muse, mutect2, varscan2
- SARDH | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 95/452 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs755121921; called by muse, mutect2, varscan2
- SASH1 | c.3177del p.W1060Gfs*16 | Frame Shift Del (DEL) | VAF 148/634 reads (23%) | catalogued as rs761606832; called by pindel, varscan2
- SATB2 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 51/336 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1321695489, COSV53481443, COSV53494145; called by muse, mutect2, varscan2
- SCAF11 | c.3845del p.P1282Lfs*29 | Frame Shift Del (DEL) | VAF 62/330 reads (19%) | catalogued as rs764655538; called by mutect2, pindel, varscan2
- SCART1 | c.2335G>A p.G779S | Missense Mutation (SNP) | VAF 90/403 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1490935077; called by muse, varscan2
- SCFD2 | c.1346A>G p.N449S | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs145483713; called by muse, mutect2, varscan2
- SCLY | c.140C>T p.T47M (on ENST00000651534; = p.T39M on NM_016510.7) | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111411095; called by muse, mutect2, varscan2
- SCN5A | c.4876C>T p.R1626C (on ENST00000333535 / NM_198056.3; = p.R1625C on NM_000335.5) | Missense Mutation (SNP) | VAF 66/297 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs918933961, COSV61118793; ClinVar: uncertain significance; called by muse, varscan2
- SCN5A | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 60/434 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752732123; called by muse, mutect2, varscan2
- SCN7A | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV99066096; called by muse, mutect2, varscan2
- SCN8A | c.5671C>T p.R1891C | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs774029281; called by muse, mutect2, varscan2
- SCUBE3 | c.2510del p.P837Hfs*27 | Frame Shift Del (DEL) | VAF 70/411 reads (17%) | catalogued as rs765256475; called by mutect2, pindel, varscan2
- SDC1 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 48/601 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as rs750695100; called by muse, mutect2
- SEC63 | c.1586_1596delinsGAAACCTTT p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 77/434 reads (18%) | catalogued as COSV64602454; called by pindel, varscan2*
- SEL1L | c.1110del p.G371Vfs*20 | Frame Shift Del (DEL) | VAF 44/300 reads (15%) | catalogued as COSV60921783; called by mutect2, pindel, varscan2
- SEL1L3 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs368115723, COSV53542135, COSV53543237; called by muse, varscan2
- SEMA4D | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369287352; called by muse, mutect2, varscan2
- SEMA6A | c.3036del p.K1013Nfs*11 | Frame Shift Del (DEL) | VAF 75/361 reads (21%) | catalogued as rs751600344; called by mutect2, pindel, varscan2
- SEMG1 | c.132G>T p.K44N | Missense Mutation (SNP) | VAF 59/320 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.565); catalogued as rs748841177; called by muse, mutect2, varscan2
- SENP7 | c.2315_2317del p.E772del | In Frame Del (DEL) | VAF 40/234 reads (17%) | catalogued as rs778689366; called by pindel, varscan2
- SENP7 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV58620934; called by muse, mutect2, varscan2
- SFXN3 | c.444-1G>T p.X148_splice | Splice Site (SNP) | VAF 23/386 reads (6%) | catalogued as COSV56521556; called by muse, mutect2
- SH3GL1 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 68/317 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.777); catalogued as rs1446140246; called by muse, mutect2, varscan2
- SH3RF2 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 76/387 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs138966950; called by muse, mutect2, varscan2
- SI | c.2873G>A p.R958H | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778886006, COSV52273192; called by muse, mutect2, varscan2
- SIDT2 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 63/312 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs138225019; called by muse, mutect2, varscan2
- SLC12A5 | c.1761C>A p.F587L (on ENST00000454036 / NM_001134771.2; = p.F564L on NM_020708.5) | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV54787520; called by muse, mutect2, varscan2
- SLC12A6 | c.3005G>A p.R1002Q (on ENST00000354181 / NM_001365088.1; = p.R951Q on NM_005135.2) | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs778685963, COSV51629531; called by muse, mutect2, varscan2
- SLC12A8 | c.735A>G p.T245= | Splice Region (SNP) | VAF 60/234 reads (26%) | catalogued as rs1409822042; called by muse, mutect2, varscan2
- SLC15A4 | c.635G>C p.G212A | Missense Mutation (SNP) | VAF 70/395 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as COSV57164141; called by muse, mutect2, varscan2
- SLC16A11 | c.1219G>A p.A407T (on ENST00000308009; = p.A383T on NM_153357.3) | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV57273874; called by muse, mutect2, varscan2
- SLC16A8 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs776738895; called by muse, mutect2, varscan2
- SLC22A11 | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 25/540 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.113); catalogued as rs1366260048; called by muse, mutect2
- SLC22A8 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 143/595 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs545835369, COSV60327594; called by muse, mutect2, varscan2
- SLC29A4 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as rs140231673, COSV51876587; called by muse, mutect2, varscan2
- SLC39A13 | c.957G>T p.W319C (on ENST00000362021 / NM_001128225.3; = p.W312C on NM_152264.4) | Missense Mutation (SNP) | VAF 84/334 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs945120461; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 46/206 reads (22%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC7A10 | c.1510_1512del p.E504del | In Frame Del (DEL) | VAF 52/294 reads (18%) | catalogued as rs773962144; called by pindel, varscan2
- SLC7A4 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 84/442 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as rs746094200, COSV60382243, COSV60384751; called by muse, mutect2, varscan2
- SLC9A3 | c.2475del p.A826Pfs*148 | Frame Shift Del (DEL) | VAF 68/302 reads (23%) | catalogued as rs766408217; called by pindel, varscan2
- SLCO4C1 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 75/400 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs777754809, COSV60517660; called by muse, mutect2, varscan2
- SLTM | c.1460del p.N487Ifs*35 | Frame Shift Del (DEL) | VAF 31/198 reads (16%) | catalogued as rs762322084; called by mutect2, varscan2
- SMTNL2 | c.490C>T p.P164S (on ENST00000389313 / NM_001114974.2; = p.P20S on NM_198501.3) | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1459130248, COSV58807557; called by muse, mutect2, varscan2
- SNAP29 | c.101_109dup p.G34_D36dup | In Frame Ins (INS) | VAF 82/472 reads (17%) | catalogued as rs754419395; called by mutect2, varscan2
- SNTG1 | c.820del p.I274Sfs*7 | Frame Shift Del (DEL) | VAF 24/179 reads (13%) | catalogued as COSV52441292; called by mutect2, pindel, varscan2
- SNX29 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs1011178448; called by muse, mutect2, varscan2
- SOGA3 | c.2378C>T p.T793M | Missense Mutation (SNP) | VAF 122/590 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV64105390; called by muse, mutect2, varscan2
- SOGA3 | c.722del p.G241Afs*133 | Frame Shift Del (DEL) | VAF 70/458 reads (15%) | catalogued as rs778091058, COSV100846885; called by mutect2, varscan2
- SORCS3 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 79/437 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as rs1250863365; called by muse, varscan2
- SOST | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 108/466 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.308); catalogued as rs763425001, COSV100059773; called by muse, mutect2, varscan2
- SOX1 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 79/377 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as rs1266821135; called by muse, mutect2, varscan2
- SOX18 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 90/493 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV100450624; called by muse, mutect2, varscan2
- SOX7 | c.463del p.A155Rfs*116 | Frame Shift Del (DEL) | VAF 107/462 reads (23%) | catalogued as rs769092194; called by mutect2, varscan2
- SP140L | c.887_888del p.V296Gfs*20 | Frame Shift Del (DEL) | VAF 42/301 reads (14%) | catalogued as rs767306474; called by pindel, varscan2
- SP2 | c.620del p.G207Afs*4 | Frame Shift Del (DEL) | VAF 101/500 reads (20%) | catalogued as COSV100947272; called by mutect2, pindel, varscan2
- SPAG16 | c.1388G>T p.W463L | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1484009851, COSV100531284; called by muse, mutect2, varscan2
- SPATC1 | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 82/607 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as rs781954923; called by muse, mutect2, varscan2
- SPDYE6 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 65/314 reads (21%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.674); catalogued as rs1233013838; called by muse, mutect2, varscan2
- SPEN | c.4424G>A p.R1475Q | Missense Mutation (SNP) | VAF 65/360 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.336); catalogued as rs141407539; called by muse, mutect2, varscan2
- SPINT2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 60/305 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.553); catalogued as rs754350392, COSV100007516, COSV56649053; called by muse, mutect2, varscan2
- SPNS1 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 88/387 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs748746793, COSV57956614; called by muse, mutect2, varscan2
- SPTA1 | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 69/272 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.426); catalogued as rs1011999071; called by muse, mutect2, varscan2
- SPTAN1 | c.3161G>A p.R1054H | Missense Mutation (SNP) | VAF 90/351 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs561564501, COSV63986436; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN1 | c.2513C>T p.T838M | Missense Mutation (SNP) | VAF 96/401 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs879005866; called by muse, mutect2, varscan2
- SREK1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs774604410, COSV52332559; called by muse, mutect2, varscan2
- SRI | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV99719848; called by muse, mutect2, varscan2
- SRPK3 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 20/485 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs782798873; called by muse, mutect2
- SRPRA | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 65/391 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs753990496; called by muse, mutect2, varscan2
- STAB1 | c.4015dup p.V1339Gfs*30 | Frame Shift Ins (INS) | VAF 81/454 reads (18%) | catalogued as rs761841917; called by mutect2, varscan2
- STAT5A | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 28/486 reads (6%) | catalogued as COSV61806976; called by muse, mutect2
- STX16 | c.722G>A p.R241H (on ENST00000371141 / NM_001001433.3; = p.R220H on NM_003763.6) | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs148806774, COSV100397634; called by muse, mutect2, varscan2
- SULF1 | c.223del p.A75Pfs*8 | Frame Shift Del (DEL) | VAF 60/370 reads (16%) | catalogued as rs747316268, COSV52690552; called by mutect2, pindel, varscan2
- SULT1C3 | c.458G>T p.R153M | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV100227461, COSV61252695; called by muse, mutect2, varscan2
- SVIL | c.4813G>A p.V1605I (on ENST00000355867 / NM_021738.3; = p.V1179I on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/326 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.251); catalogued as rs377161548; called by muse, mutect2, varscan2
- SYBU | c.70C>T p.R24* (on ENST00000276646 / NM_001099754.2; = p.R23* on NM_017786.6) | Nonsense Mutation (SNP) | VAF 61/480 reads (13%) | catalogued as rs770097369, COSV99406667; called by muse, mutect2, varscan2
- SYMPK | c.3724C>T p.R1242W | Missense Mutation (SNP) | VAF 92/449 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs752519438; called by muse, mutect2, varscan2
- SYNE1 | c.12697del p.E4233Kfs*14 (on ENST00000367255 / NM_182961.4; = p.E4162Kfs*14 on NM_033071.3) | Frame Shift Del (DEL) | VAF 87/435 reads (20%) | catalogued as COSV99556709; called by mutect2, pindel, varscan2
- SYNE1 | c.5123C>A p.S1708Y (on ENST00000367255 / NM_182961.4; = p.S1715Y on NM_033071.3) | Missense Mutation (SNP) | VAF 13/319 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV54947553; called by muse, mutect2
- SYNJ1 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 49/286 reads (17%) | catalogued as rs756965178, COSV59147096; called by muse, mutect2, varscan2
- SYNRG | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 77/326 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); catalogued as rs771522636; called by muse, mutect2, varscan2
- SYVN1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 69/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766219891; called by muse, mutect2, varscan2
- TACR3 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 92/452 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as rs755230221; called by muse, varscan2
- TCF15 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs1246134607; called by muse, mutect2
- TCF7L1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 82/433 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs769416345; called by muse, mutect2, varscan2
- TCTEX1D4 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 150/626 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1007873549, COSV59499005; called by muse, mutect2, varscan2
- TDRD6 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 78/547 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as rs534072901, COSV100287109; called by muse, mutect2, varscan2
- TDRD9 | c.4020G>A p.W1340* | Nonsense Mutation (SNP) | VAF 77/327 reads (24%) | catalogued as rs764643824; called by muse, mutect2, varscan2
- TECTA | c.4501G>A p.A1501T | Missense Mutation (SNP) | VAF 107/493 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1056976311, COSV50688097; called by muse, mutect2, varscan2
- TELO2 | c.2504C>T p.A835V | Missense Mutation (SNP) | VAF 57/283 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.013); catalogued as rs375348828, COSV99248529; called by muse, mutect2, varscan2
- TENM1 | c.3193C>T p.R1065* | Nonsense Mutation (SNP) | VAF 94/452 reads (21%) | catalogued as COSV64443370; called by muse, varscan2
- TEX15 | c.7523C>T p.A2508V (on ENST00000256246; = p.A2891V on NM_001350162.2) | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs908404536, COSV56349697; called by muse, mutect2, varscan2
- TEX49 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs1254229682, COSV100326418; called by muse, mutect2, varscan2
- TFAM | c.440_441del p.K147Rfs*16 | Frame Shift Del (DEL) | VAF 15/123 reads (12%) | catalogued as rs544132101; called by mutect2, varscan2
- TFAP4 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 74/396 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52596985; called by muse, mutect2, varscan2
- TFEC | c.422del p.K141Rfs*42 | Frame Shift Del (DEL) | VAF 36/218 reads (17%) | catalogued as rs771133493, COSV55406589; called by mutect2, pindel, varscan2
- THBS1 | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs566689933; called by muse, mutect2, varscan2
- THBS4 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.239); catalogued as rs553602331, COSV63470130; called by muse, mutect2, varscan2
- THSD7B | c.1139C>A p.P380H | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99755997; called by muse, mutect2
- TIAM2 | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 71/363 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100017941; called by muse, mutect2, varscan2
- TLR9 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 83/455 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV100645526; called by muse, mutect2, varscan2
- TMC1 | c.1386G>T p.M462I | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52781537; called by muse, mutect2, varscan2
- TMEFF2 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV99771118; called by muse, mutect2, varscan2
- TMEM104 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 107/488 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs558638179; called by muse, mutect2, varscan2
- TMEM127 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.263); catalogued as rs866711036; called by muse, mutect2
- TMEM165 | c.345dup p.I116Yfs*10 | Frame Shift Ins (INS) | VAF 47/304 reads (15%) | catalogued as rs1369064334; called by mutect2, pindel, varscan2
- TMEM187 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 129/654 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs782508666, COSV64142313; called by muse, mutect2, varscan2
- TMEM200C | c.1089del p.R364Afs*13 | Frame Shift Del (DEL) | VAF 117/608 reads (19%) | catalogued as rs1237699327; called by mutect2, pindel, varscan2
- TMEM215 | c.228G>A p.W76* | Nonsense Mutation (SNP) | VAF 94/443 reads (21%) | catalogued as COSV61363335; called by muse, mutect2, varscan2
- TMEM248 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 85/421 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as rs150737683; called by muse, mutect2, varscan2
- TMEM255B | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 64/321 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1566741744, COSV99057360; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 48/211 reads (23%) | catalogued as rs770800449; called by mutect2, varscan2
- TNK2 | c.1732G>A p.V578M | Missense Mutation (SNP) | VAF 148/713 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.163); catalogued as rs375205272, COSV57377311; ClinVar: benign; called by muse, varscan2
- TNS1 | c.3300C>A p.D1100E | Missense Mutation (SNP) | VAF 105/456 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV99411386; called by muse, mutect2, varscan2
- TOGARAM1 | c.3323G>A p.G1108E | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63891337; called by muse, mutect2, varscan2
- TPST2 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 106/543 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.434); catalogued as rs531917631, COSV58681457; called by muse, mutect2, varscan2
- TRAPPC9 | c.3277G>A p.A1093T | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs755892862; called by muse, mutect2, varscan2
- TRBV4-2 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 20/410 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.107); catalogued as rs1381724074; called by muse, mutect2
- TREX2 | c.709G>A p.V237M (on ENST00000334497; = p.V194M on NM_080701.3) | Missense Mutation (SNP) | VAF 131/656 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556979239; called by muse, mutect2, varscan2
- TRIM2 | c.1087G>A p.A363T (on ENST00000437508; = p.A390T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/454 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs754123914; called by muse, mutect2, varscan2
- TRPM3 | c.4519C>T p.R1507C (on ENST00000357533 / NM_001366142.2; = p.R1362C on NM_020952.6) | Missense Mutation (SNP) | VAF 68/347 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1035251103, COSV62596606; called by muse, mutect2, varscan2
- TSBP1 | c.670del p.S224Lfs*8 (on ENST00000617061; = p.S227Lfs*8 on NM_006781.5) | Frame Shift Del (DEL) | VAF 52/317 reads (16%) | catalogued as COSV66660771; called by mutect2, varscan2
- TSHR | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 17/335 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as CM052932, COSV53324473; called by muse, mutect2
- TSPOAP1 | c.5213G>A p.R1738H | Missense Mutation (SNP) | VAF 80/343 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs772806875, COSV52113023; called by muse, mutect2, varscan2
- TSSK2 | c.825del p.K276Sfs*30 | Frame Shift Del (DEL) | VAF 76/428 reads (18%) | catalogued as rs764514103; called by mutect2, pindel, varscan2
- TTC22 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 91/429 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.945); catalogued as COSV64881107; called by muse, mutect2, varscan2
- TTC28 | c.4787C>T p.S1596L | Missense Mutation (SNP) | VAF 30/576 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.131); catalogued as rs760684559, COSV67414880; called by muse, mutect2
- TTC3 | c.1769del p.N590Tfs*4 | Frame Shift Del (DEL) | VAF 54/198 reads (27%) | catalogued as rs752525442; called by mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 27/155 reads (17%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 91/315 reads (29%) | catalogued as rs1347415564, COSV60385937; called by muse, mutect2, varscan2
- TUBB8B | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated, low confidence (0.05); catalogued as rs779797128; called by muse, varscan2
- TUBG1 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 90/464 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780924021; called by muse, mutect2, varscan2
- TUT4 | c.2522C>T p.S841L | Missense Mutation (SNP) | VAF 61/307 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.141); catalogued as rs765761860, COSV99931920, COSV99932961; called by muse, mutect2, varscan2
- TXNL4A | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 80/431 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV54099104; called by muse, mutect2, varscan2
- TXNL4B | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 138/324 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as rs778134996, COSV99194220; called by muse, mutect2, varscan2
- UBA1 | c.3133G>A p.G1045S | Missense Mutation (SNP) | VAF 72/370 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs782451807; called by muse, mutect2, varscan2
- UBR1 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1567131023, CM144365, COSV51936762; called by muse, mutect2, varscan2
- UCP2 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs761798872, COSV60104558; called by muse, mutect2, varscan2
- UFSP1 | c.196del p.D66Tfs*14 | Frame Shift Del (DEL) | VAF 32/340 reads (9%) | catalogued as rs751446699; called by mutect2, pindel
- UGDH | c.214del p.S72Lfs*18 | Frame Shift Del (DEL) | VAF 42/206 reads (20%) | catalogued as rs765734647, COSV57097233; called by mutect2, varscan2
- UGT1A6 | c.1560del p.R522Efs*22 | Frame Shift Del (DEL) | VAF 42/262 reads (16%) | catalogued as COSV59381895; called by mutect2, varscan2
- ULK2 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 80/365 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs749044855; called by muse, mutect2, varscan2
1,477 further variants in this file (874 protein-altering or splice-affecting, 536 silent, 67 other) are not listed here.
